Gene-level copy-number profile of tumor specimen TCGA-DK-AA77-01A from TCGA case TCGA-DK-AA77, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 61.2 years (22,365 days).
Specimen TCGA-DK-AA77-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0eb941af-5011-4ebf-ad65-943e57475ab3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA77-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c3db5dc-6d87-456f-a784-a096fde54985

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 12,023; copy number 2: 43,230; copy number 3: 4,175; copy number 4: 178; copy number 5: 97; copy number 6: 8; copy number 7: 28; copy number 8: 51; copy number 13: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA77-01A-11D-A390-01): tumor purity 0.88, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 188 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,003,942–46,584,688, 14 genes, copy number 5–7 (within-gene range 4–7): RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ.
- chr2:46,698,940–47,345,074, 15 genes, copy number 7 (within-gene range 4–7): LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2.
- chr2:48,809,340–53,486,280, 36 genes, copy number 5 (within-gene range 4–5): AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1.
- chr4:98,871,684–99,654,648, 26 genes, copy number 8: EIF4E, TBCAP3, AC019131.1, FAM177A1P1, AC019131.3, RNU7-149P, NDUFS5P4, METAP1, MIR3684, ABT1P1, AC019131.2, ADH5, AP002026.1, ADH4, PCNAP1, ADH6, ADH1A, ADH1B, ADH1C, ADH7, AP001960.1, C4orf17, TRMT10A, MTTP, AC083902.1, C4orf54.
- chr4:101,972,423–104,734,546, 37 genes, copy number 6–13 (within-gene range 1–13): MTND5P5, AP002075.1, SLC39A8, RN7SL728P, AC098487.1, AF213884.2, AF213884.3, NFKB1, MANBA, AF213884.1, LRRC37A15P, KRT8P46, AC018797.1, AC018797.2, UBE2D3, AC018797.3, UBE2D3-AS1, RNU7-151P, CISD2, SLC9B1, PABPC1P7, ACTR3BP4, SLC9B2, BDH2, CENPE, LINC02428, AC105460.2, AC105460.1, DDX3P3, TACR3, AC004047.1, RNU6-635P, LINC02503, AC004052.1, CXXC4, CXXC4-AS1, AC004063.1.
- chr18:22,347,846–25,352,190, 60 genes, copy number 5 (within-gene range 2–5): AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1.

Autosomal genes at a single copy (total copy number 1): 9,602. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
